Gene-level copy-number profile of tumor specimen HTMCP-03-06-02099-01B from CGCI case HTMCP-03-06-02099, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02099-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da28b324-6af7-48db-b17d-79bf924377a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02099-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/fdfa7047-d074-4488-95c0-3e31fc5bef7f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,056; copy number 2: 10,389; copy number 3: 25,905; copy number 4: 13,796; copy number 5: 1,175; copy number 6: 3,834; copy number 7: 981; copy number 8: 710; copy number 9: 422; copy number 10: 1; copy number 11: 7; copy number 13: 1; copy number 15: 14; copy number 24: 2; copy number 25: 24; copy number 28: 2; copy number 41: 22.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr4:9,153,296–9,231,233, 8 genes: FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P.
- chr4:9,239,130–9,245,471, 2 genes (within-gene range 0–2): USP17L16P, USP17L17.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:8,059,572–8,226,614, 8 genes: AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,183 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,903,318–152,196,699, 123 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:175,944,831–176,447,919, 10 genes, copy number 7: COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr1:234,957,231–236,286,960, 44 genes, copy number 7: AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, GPR137B, ERO1B, RNU2-70P, AL450309.1.
- chr3:119,703,022–122,793,831, 71 genes, copy number 7 (broad region; genes not listed).
- chr3:135,925,891–137,011,085, 23 genes, copy number 7: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:157,814,822–158,088,997, 1 gene, copy number 7 (within-gene range 6–7): AC079943.2.
- chr3:158,095,905–158,545,730, 5 genes, copy number 7 (within-gene range 6–7): SHOX2, RSRC1, AC074276.1, AC074276.2, AC106707.2.
- chr3:170,345,678–170,418,615, 3 genes, copy number 8: AC073288.1, SKIL, AC073288.2.
- chr3:193,740,471–198,123,232, 157 genes, copy number 7 (broad region; genes not listed).
- chr7:38,239,580–38,335,514, 15 genes, copy number 7: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr11:83,072,052–85,627,922, 24 genes, copy number 7 (within-gene range 6–7): RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1.
- chr11:94,493,979–94,876,748, 9 genes, copy number 9 (within-gene range 5–9): ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1.
- chr11:97,657,464–103,479,863, 70 genes, copy number 11–41 (broad region; genes not listed).
- chr11:104,445,868–104,919,073, 5 genes, copy number 8–10: LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP.
- chr11:110,355,130–110,464,884, 2 genes, copy number 24: LINC02732, FDX1.
- chr14:22,197,446–22,482,959, 1 gene, copy number 7 (within-gene range 6–7): AC244502.1.
- chr14:22,265,749–22,483,069, 27 genes, copy number 7: TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr19:31,787,148–58,574,797, 1,592 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,056. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
